Somatic mutation profile of tumor specimen TARGET-40-NAAVMJ-01A (aliquot TARGET-40-NAAVMJ-01A-01D) from TARGET case TARGET-40-NAAVMJ, project TARGET-OS (Osteosarcoma). Sex at birth: male; Primary diagnosis: Osteosarcoma, NOS; Age at diagnosis: 17.0 years (6,205 days).
Specimen TARGET-40-NAAVMJ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 30bc2772-f450-4e1b-a129-028a403d7af6.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-40-NAAVMJ-10A (Blood Derived Normal), aliquot TARGET-40-NAAVMJ-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4ac1d4e4-7374-43be-ae4d-285fa6f1305e

The open-access MAF lists 3 somatic variants for this specimen: 2 protein-altering or splice-affecting, 1 silent.
By variant classification: Nonsense Mutation 1, Missense Mutation 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CSMD3 | c.8234G>A p.W2745* | Nonsense Mutation (SNP) | VAF 146/293 reads (50%) | called by muse, mutect2, varscan2
- MRTFB | c.98A>G p.Q33R | Missense Mutation (SNP) | VAF 63/129 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- TPX2 | c.615G>A p.K205= | Silent (SNP) | VAF 26/49 reads (53%) | called by muse, mutect2, varscan2
